Somatic mutation profile of tumor specimen HCM-BROD-0960-C16-06A (aliquot HCM-BROD-0960-C16-06A-01D-A87L-36) from HCMI case HCM-BROD-0960-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 64.5 years (23,555 days).
Specimen HCM-BROD-0960-C16-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd5a7de3-e584-4f61-949e-c5583043c7bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0960-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0960-C16-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9b14188-a5e4-4c5d-8ffa-5bd734d24b1a

The open-access MAF lists 143 somatic variants for this specimen: 111 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 29, Nonsense Mutation 7, Frame Shift Del 5, Splice Region 2, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH5 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 178/391 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777164, CM1310653, COSV59758318, COSV59758899; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ACTR8 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 236/483 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1452684482, COSV51635281; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3321G>T p.M1107I | Missense Mutation (SNP) | VAF 112/447 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1305527843, COSV54469581; called by muse, mutect2, varscan2
- ADCY8 | c.1822T>C p.S608P | Missense Mutation (SNP) | VAF 277/585 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs368131389; called by muse, mutect2, varscan2
- AHI1 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1383950113; called by muse, mutect2
- ANKRD50 | c.2729G>A p.G910D | Missense Mutation (SNP) | VAF 108/469 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs201831324; called by muse, mutect2, varscan2
- BEST3 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 125/412 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs750674581, COSV58302493; called by muse, mutect2, varscan2
- BHMT | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 202/445 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.44); catalogued as COSV57153503; called by muse, mutect2, varscan2
- C1QTNF9 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 156/706 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs780428044; called by muse, mutect2, varscan2
- CCDC146 | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs749099744; called by muse, mutect2, varscan2
- CEP68 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 304/356 reads (85%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs777440099; called by muse, mutect2, varscan2
- CGN | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 289/705 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs768433517; called by muse, mutect2, varscan2
- COL12A1 | c.2731T>G p.L911V | Missense Mutation (SNP) | VAF 95/391 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV59389600; called by muse, mutect2, varscan2
- COL24A1 | c.632A>C p.N211T | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as COSV100992911; called by muse, mutect2, varscan2
- CPEB4 | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 247/567 reads (44%) | catalogued as COSV99436928; called by muse, mutect2, varscan2
- DOCK2 | c.1240C>G p.P414A | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56960620, COSV56994482; called by muse, mutect2, varscan2
- EFHB | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV55546406; called by muse, mutect2, varscan2
- ELFN1 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 312/595 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs573849227; called by muse, mutect2, varscan2
- EPHA5 | c.2903G>C p.R968T | Missense Mutation (SNP) | VAF 163/309 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as COSV56656565; called by muse, mutect2
- FSIP2 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 140/386 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs997432494; called by muse, mutect2, varscan2
- HIVEP3 | c.6703G>T p.A2235S | Missense Mutation (SNP) | VAF 141/672 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs751800969; called by muse, mutect2, varscan2
- HOXA2 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 94/367 reads (26%) | catalogued as COSV56066750; called by muse, mutect2, varscan2
- HUWE1 | c.8746G>A p.D2916N | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.094); catalogued as rs369858708; called by muse, mutect2, varscan2
- IMP4 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 116/437 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1250160431; called by muse, mutect2, varscan2
- KRT81 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 74/503 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs1490837490, COSV100576973; called by muse, mutect2, varscan2
- MCM6 | c.1342G>C p.A448P | Missense Mutation (SNP) | VAF 160/425 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51469564; called by muse, mutect2, varscan2
- NCAM2 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 184/318 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs573485921; called by muse, mutect2, varscan2
- OCSTAMP | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 132/343 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1003265035, COSV54096647; called by muse, mutect2, varscan2
- PANK1 | c.1172C>T p.P391L (on ENST00000307534 / NM_148977.2; = p.P166L on NM_138316.4) | Missense Mutation (SNP) | VAF 269/614 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV56810784; called by muse, mutect2, varscan2
- PHACTR3 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 218/576 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV63025184; called by muse, varscan2
- PLEKHG4 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 220/468 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64613161; called by muse, mutect2, varscan2
- POLN | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 86/345 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs193920976, COSV67024190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRT | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 104/584 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs724159842, COSV61985408, COSV61985479, COSV62019583; called by muse, mutect2, varscan2
- RIPK1 | c.764A>T p.Y255F | Missense Mutation (SNP) | VAF 182/421 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs567232503; called by muse, mutect2, varscan2
- ROBO2 | c.4063C>T p.R1355C | Missense Mutation (SNP) | VAF 184/323 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs554936963, COSV59901001, COSV59948476; called by muse, mutect2, varscan2
- ROGDI | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 146/368 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs566665742, COSV59021973; called by muse, mutect2, varscan2
- RTN4RL2 | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 33/416 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100625432; called by muse, mutect2
- SCGN | c.153T>C p.D51= | Splice Region (SNP) | VAF 128/312 reads (41%) | catalogued as rs746274904; called by muse, mutect2, varscan2
- SERPINA7 | c.437T>G p.F146C | Missense Mutation (SNP) | VAF 131/318 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59667139; called by muse, mutect2, varscan2
- SLC25A33 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 172/412 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as rs917378356; called by muse, mutect2, varscan2
- SLC7A3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 344/376 reads (91%) | SIFT tolerated (0.43); PolyPhen benign (0.171); catalogued as rs776425784, COSV53227212; called by muse, mutect2, varscan2
- SLCO2B1 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 83/421 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56938961; called by muse, mutect2, varscan2
- SMAD6 | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 173/539 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1278620954; called by muse, mutect2, varscan2
- SMC4 | c.818G>C p.R273T | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1196542918; called by muse, mutect2
- SVEP1 | c.8438G>T p.R2813I | Missense Mutation (SNP) | VAF 213/532 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.426); catalogued as rs558094894, COSV99929893; called by muse, mutect2, varscan2
- TENM4 | c.5888G>A p.R1963Q | Missense Mutation (SNP) | VAF 76/480 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs539606746, COSV53673736; called by muse, mutect2, varscan2
- TTLL3 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs770320325; called by muse, mutect2
- TTN | c.25489G>A p.D8497N (on ENST00000591111; = p.D7570N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 293/557 reads (53%) | PolyPhen probably damaging (0.926); catalogued as rs1035364658, COSV60349639; called by muse, mutect2, varscan2
- TULP4 | c.3823C>T p.P1275S | Missense Mutation (SNP) | VAF 157/544 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs774770935; called by muse, mutect2, varscan2
- USH2A | c.15581G>A p.R5194H | Missense Mutation (SNP) | VAF 184/413 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs727505155, COSV52065509; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZC3H12A | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 247/510 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1035304408; called by muse, mutect2, varscan2
- ZSCAN1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs557413199, COSV56608327; called by muse, mutect2, varscan2
- ABCA9 | c.4688C>A p.P1563H | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAMTS16 | c.997G>T p.G333* | Nonsense Mutation (SNP) | VAF 123/321 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.1846G>A p.A616T (on ENST00000361247 / NM_001162383.2; = p.A588T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 138/673 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ARRDC4 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 68/519 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ATP1A3 | c.2839G>A p.V947I (on ENST00000545399 / NM_001256214.2; = p.V934I on NM_152296.5) | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BCL7A | c.226A>C p.T76P | Missense Mutation (SNP) | VAF 94/372 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRIP1 | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 121/336 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CAMK4 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, varscan2
- CCDC136 | c.783G>A p.R261= | Splice Region (SNP) | VAF 165/275 reads (60%) | called by muse, mutect2, varscan2
- CCNDBP1 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 69/256 reads (27%) | called by muse, mutect2, varscan2
- CEP350 | c.8847del p.P2950Lfs*12 | Frame Shift Del (DEL) | VAF 178/495 reads (36%) | called by mutect2, pindel, varscan2
- CHD5 | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 269/605 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DISP1 | c.3569A>C p.E1190A | Missense Mutation (SNP) | VAF 88/468 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ENAM | c.3230G>T p.G1077V | Missense Mutation (SNP) | VAF 132/434 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM98C | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 96/338 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXW8 | c.622G>A p.A208T (on ENST00000309909; = p.A246T on NM_012174.1) | Missense Mutation (SNP) | VAF 108/434 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FOXN4 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 140/453 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- GOLGA4 | c.412del p.Q138Sfs*2 | Frame Shift Del (DEL) | VAF 175/443 reads (40%) | called by mutect2, pindel, varscan2
- GPR107 | c.1480_1481del p.F494Qfs*15 (on ENST00000372406 / NM_001136557.2; = p.F446Qfs*15 on NM_020960.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 71/258 reads (28%) | called by mutect2, pindel, varscan2
- HCRT | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 293/651 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- HUWE1 | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IRX1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LEFTY2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 358/800 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- MUC6 | c.4339_4345del p.V1447Lfs*7 | Frame Shift Del (DEL) | VAF 200/348 reads (57%) | called by pindel, varscan2
- MYLK | c.2719A>G p.T907A | Missense Mutation (SNP) | VAF 246/617 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NLRP1 | c.4381G>A p.E1461K (on ENST00000572272 / NM_033004.4; = p.E1417K on NM_014922.5) | Missense Mutation (SNP) | VAF 71/338 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- OR13F1 | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 133/304 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2J3 | c.799T>G p.S267A | Missense Mutation (SNP) | VAF 182/437 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- OR56A4 | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 212/525 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR8K3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 228/297 reads (77%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH15 | c.5056A>G p.K1686E (on ENST00000644397 / NM_001354429.2; = p.K1628E on NM_001142771.2) | Missense Mutation (SNP) | VAF 225/544 reads (41%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PCDHB15 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 152/355 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PDE6C | c.1661A>C p.K554T | Missense Mutation (SNP) | VAF 148/335 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PHACTR3 | c.722C>A p.A241E | Missense Mutation (SNP) | VAF 198/587 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.084); called by muse, varscan2
- PHF3 | c.2758T>G p.S920A | Missense Mutation (SNP) | VAF 243/580 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKD1L3 | c.4207C>A p.H1403N | Missense Mutation (SNP) | VAF 228/541 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PPIP5K2 | c.3625A>T p.S1209C (on ENST00000358359 / NM_001276277.3; = p.S1188C on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/245 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSIP1 | c.1088T>G p.L363R | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRZ1 | c.2951T>C p.L984P | Missense Mutation (SNP) | VAF 157/482 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PXDN | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 265/629 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM34 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 64/320 reads (20%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 128/152 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- RTL1 | c.678C>A p.S226R | Missense Mutation (SNP) | VAF 217/512 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RXYLT1 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGO2 | c.2157G>C p.K719N | Missense Mutation (SNP) | VAF 197/409 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SLCO1B3 | c.895C>A p.L299M | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SS18L1 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 85/458 reads (19%) | called by muse, mutect2, varscan2
- STKLD1 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 190/441 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SYCP1 | c.906G>C p.K302N | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SYNE3 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 149/676 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TFAP2A | c.421G>A p.A141T (on ENST00000482890; = p.A133T on NM_001032280.3) | Missense Mutation (SNP) | VAF 230/525 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIB1 | c.726dup p.H243Tfs*10 | Frame Shift Ins (INS) | VAF 250/681 reads (37%) | called by mutect2, pindel, varscan2
- TRIM5 | c.1292_1293del p.V431Dfs*5 | Frame Shift Del (DEL) | VAF 176/502 reads (35%) | called by pindel, varscan2
- TRPC3 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 300/478 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, varscan2
- ULK2 | c.2882C>G p.A961G | Missense Mutation (SNP) | VAF 34/861 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- WDFY3 | c.5916C>G p.D1972E | Missense Mutation (SNP) | VAF 110/471 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZFHX3 | c.3502G>T p.E1168* | Nonsense Mutation (SNP) | VAF 202/519 reads (39%) | called by muse, mutect2, varscan2
- ZGRF1 | c.5691G>A p.M1897I | Missense Mutation (SNP) | VAF 95/426 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF292 | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 122/324 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGB | c.3606T>C p.Y1202= | Silent (SNP) | VAF 205/451 reads (45%) | catalogued as COSV62230399; called by muse, mutect2, varscan2
- ANKFY1 | c.2886C>T p.G962= (on ENST00000341657 / NM_001330063.2; = p.G963= on NM_016376.5) | Silent (SNP) | VAF 169/283 reads (60%) | catalogued as rs746572099, COSV58918612; called by muse, mutect2, varscan2
- AOX1 | c.3972G>C p.P1324= | Silent (SNP) | VAF 151/515 reads (29%) | called by muse, mutect2, varscan2
- C1orf112 | c.2301A>G p.K767= | Silent (SNP) | VAF 111/554 reads (20%) | catalogued as COSV53683052; called by muse, mutect2, varscan2
- CHI3L2 | c.546G>A p.A182= | Silent (SNP) | VAF 156/329 reads (47%) | catalogued as rs143811682; called by muse, mutect2, varscan2
- CUL9 | c.402G>A p.G134= | Silent (SNP) | VAF 160/710 reads (23%) | called by muse, mutect2, varscan2
- DOCK9 | c.5706G>A p.T1902= (on ENST00000376460 / NM_001366676.2; = p.T1903= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 114/488 reads (23%) | catalogued as rs752584573; called by muse, mutect2, varscan2
- FAM135B | c.735C>T p.C245= | Silent (SNP) | VAF 214/487 reads (44%) | called by muse, mutect2, varscan2
- FANCM | c.1734C>A p.G578= | Silent (SNP) | VAF 124/307 reads (40%) | called by muse, mutect2, varscan2
- HAUS5 | c.306G>A p.E102= | Silent (SNP) | VAF 114/395 reads (29%) | called by muse, mutect2, varscan2
- HMCN1 | c.3660C>T p.S1220= | Silent (SNP) | VAF 82/644 reads (13%) | called by muse, mutect2, varscan2
- INSM1 | c.576C>T p.A192= | Silent (SNP) | VAF 106/520 reads (20%) | called by muse, mutect2, varscan2
- KRTAP2-3 | c.99C>T p.P33= | Silent (SNP) | VAF 158/581 reads (27%) | catalogued as rs1462891070; called by muse, mutect2, varscan2
- MAGEC1 | c.3066G>A p.V1022= | Silent (SNP) | VAF 60/287 reads (21%) | called by muse, mutect2, varscan2
- MMP14 | c.1320A>G p.E440= | Silent (SNP) | VAF 143/381 reads (38%) | called by muse, mutect2, varscan2
- NFKBIB | c.165T>G p.T55= | Silent (SNP) | VAF 93/371 reads (25%) | called by muse, mutect2, varscan2
- OR4A16 | c.741C>T p.L247= | Silent (SNP) | VAF 198/260 reads (76%) | catalogued as rs1346457574, COSV100125249, COSV59043426, COSV59045211; called by muse, mutect2, varscan2
- PAX1 | c.222C>T p.A74= | Silent (SNP) | VAF 132/666 reads (20%) | called by muse, mutect2, varscan2
- PCDHB13 | c.2313C>T p.I771= | Silent (SNP) | VAF 86/464 reads (19%) | catalogued as rs782235018, COSV53394613; called by muse, mutect2, varscan2
- PLCL2 | c.3366C>T p.N1122= (on ENST00000615277 / NM_001144382.2; = p.N996= on NM_015184.5) | Silent (SNP) | VAF 60/283 reads (21%) | catalogued as rs141251542, COSV69055533; called by muse, mutect2, varscan2
- PRKCZ | c.723C>A p.I241= | Silent (SNP) | VAF 200/436 reads (46%) | called by muse, mutect2, varscan2
- RPL3L | c.750G>A p.K250= | Silent (SNP) | VAF 280/642 reads (44%) | catalogued as COSV51907163; called by muse, varscan2
- RTL8C | c.78G>C p.P26= | Silent (SNP) | VAF 107/287 reads (37%) | catalogued as COSV57060139; called by mutect2, varscan2
- SDHAF3 | c.6G>C p.P2= | Silent (SNP) | VAF 62/240 reads (26%) | catalogued as rs566561181; called by muse, mutect2, varscan2
- SYNE3 | c.1074C>T p.G358= | Silent (SNP) | VAF 149/675 reads (22%) | called by muse, mutect2, varscan2
- TNR | c.1014C>T p.S338= | Silent (SNP) | VAF 43/426 reads (10%) | catalogued as rs779406233, COSV54891052; called by muse, mutect2, varscan2
- TOR1AIP2 | c.6C>T p.A2= | Silent (SNP) | VAF 40/368 reads (11%) | catalogued as rs774160953; called by muse, mutect2
- UBR4 | c.11100C>T p.C3700= | Silent (SNP) | VAF 101/247 reads (41%) | called by muse, mutect2, varscan2
- ZNF184 | c.882T>A p.T294= | Silent (SNP) | VAF 19/642 reads (3%) | called by muse, mutect2
- ASTN2 | c.*238_*239del | 3'UTR (DEL) | VAF 22/189 reads (12%) | called by pindel, varscan2
- DCAF13 | chr8:103415233 del AAGCGACTGCACAGCTA | 5'Flank (DEL) | VAF 199/495 reads (40%) | called by mutect2, pindel, varscan2
- YME1L1 | c.339+52T>A | Intron (SNP) | VAF 263/597 reads (44%) | called by muse, mutect2, varscan2
